Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8167, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8167-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med: Rec.: [REDACTED]

Phone Number: [REDACTED]

DOB: [REDACTED]

Gender: F

Client: [REDACTED]

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

CLINICAL HISTORY

Right temporal tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, right temporal tumor, excision biopsy
B: Brain, right temporal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B, Brain, right temporal tumor, excision biopsy:
Oligoastrocytoma WHO
grade II (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis of infiltrating glioma. Many tumor cells show roundish nuclei and occasional pericellular halos. Angular nuclei are also noted however the oligodendroglial component may be dominant. Mitotic activity is not conspicuous. Necrosis and vascular proliferation are not seen. [REDACTED] slides are also examined. The Ki-67 labeling index is up to approximately 7%. Controls show appropriate reactivity.

Results of additional studies will be reported below in procedure addenda.

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

[page 2 of 5]
Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S1612, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[page 3 of 5]
[REDACTED]

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Immunohistology

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

An experimental antibody for the R132H IDH1 mutation is positive.

[page 4 of 5]
Results-Comments

An IDH1 R132H mutation immunostain was performed on a section from

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, right temporal tumor, excision biopsy: Atypical glial proliferation consistent with infiltrating glioma. Frozen section and smears performed at [REDACTED] and results reported to the Physician of [REDACTED] Record.

GROSS DESCRIPTION

A. Brain, right temporal tumor, excision biopsy:
CONTAINER LABEL: right temporal.
FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 1.5 x 1.2 x 1 cm.
CASSETTES:
3, NS.

B. Brain, right temporal tumor, excision biopsy:
CONTAINER LABEL: right temporal tumor.
FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 1 x 0.3 x 0.2 cm.
CASSETTES:
1, NS.

ICD-9(s):
191.2 191.2

Histo Data

Part A: Brain, right temporal tumor, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
H/E x 1	1		
TPS H/E x 1	1		
H/E x 1	2		
H/E x 1	3		
LOH-curles x 1	3		
MGMT-curles x 1	3		
MIB1-DA x 1	3		
idh1			Please also run
antibody.			

[page 5 of 5]
Part B: Brain, right temporal tumor, excision biopsy

Taken:	[REDACTED]	Received:	[REDACTED]	
Stain/cnt		Block	Ordered	Comment
H/E x 1		1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 47ae53ba-8347-45e8-a376-9d04921d1b5e (TCGA-DU-8167.8C93CC66-38B1-451F-B941-FCA73C10C651.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).